Gene-level copy-number profile of tumor specimen TCGA-06-0184-01A from TCGA case TCGA-06-0184, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.8 years (23,317 days).
Specimen TCGA-06-0184-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.762f368f-acfb-4cdc-bde3-bd4fdd8e0cc7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0184-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e1103989-8c6c-48ce-b70a-7c55fcd8e8c3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 18,184; copy number 2: 39,150; copy number 3: 850; copy number 4: 926; copy number 5: 188; copy number 6: 415; copy number 7: 105.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0184-01A-01D-0236-01): tumor purity 0.62, ploidy 1.74, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 708 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–2,242,215, 59 genes, copy number 5 (within-gene range 2–5): AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1, C7orf50, MIR339, AC073957.1, GPR146, AC073957.2, AC091729.1, AC091729.2, GPER1, ZFAND2A, ZFAND2A-DT, UNCX, AC073094.1, MICALL2, AC102953.1, AC102953.2, INTS1, AC093734.1, MAFK, TMEM184A, PSMG3, PSMG3-AS1, TFAMP1, AC074389.2, ELFN1, AC074389.3, AC074389.1, ELFN1-AS1, MAD1L1, AC069288.1, AC104129.1, MIR4655.
- chr7:25,593,304–26,995,239, 21 genes, copy number 6 (within-gene range 4–6): AC005165.1, AC005165.2, AC005165.3, AC018706.1, AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3, AC010677.2, AC010677.1, SNX10, AC004540.2, AC004540.1, KIAA0087, AC004947.2, AC004947.1, AC004947.3, LINC02860, SKAP2, RPL7AP38.
- chr7:27,412,164–30,993,254, 73 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:32,427,901–37,449,249, 92 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:51,614,251–56,617,957, 104 genes, copy number 5–7 (broad region; genes not listed).
- chr7:64,768,156–65,100,232, 21 genes, copy number 6: AC073349.3, ZNF138, AC073349.4, AC073349.2, SEPHS1P1, EEF1DP4, AC073349.5, ZNF273, AC073349.1, VN1R42P, MTDHP1, AC073210.3, ZNF117, ERV3-1, RNU6-1229P, CCT6P3, AC073210.2, SNORA22C, SNORA15B-1, AC073210.1, GTF2IP14.
- chr7:65,463,071–65,463,438, 1 gene, copy number 7: AC114501.3.
- chr7:79,768,028–80,391,474, 7 genes, copy number 6 (within-gene range 4–6): GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P.
- chr7:106,624,072–107,161,811, 7 genes, copy number 7 (within-gene range 4–7): AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1.
- chr7:110,662,644–111,562,517, 1 gene, copy number 6 (within-gene range 4–6): IMMP2L.
- chr7:111,091,006–113,451,402, 31 genes, copy number 6: LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30, AC073137.1, AC073348.1.
- chr7:116,524,994–123,829,252, 103 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr7:127,997,597–131,754,252, 133 genes, copy number 6 (broad region; genes not listed).
- chr7:153,887,097–154,894,285, 1 gene, copy number 6 (within-gene range 4–6): DPP6.
- chr7:154,544,169–155,645,205, 31 genes, copy number 6: AC024730.1, AC073336.1, PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.5, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.3, AC009403.1.
- chr7:156,388,922–157,503,908, 23 genes, copy number 6 (within-gene range 4–6): LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1.

Autosomal genes at a single copy (total copy number 1): 15,803. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
